Gene-level copy-number profile of tumor specimen TCGA-AJ-A3IA-01A from TCGA case TCGA-AJ-A3IA, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 77.9 years (28,470 days).
Specimen TCGA-AJ-A3IA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.38b2804b-97da-4b71-8b16-6342a40f97b0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AJ-A3IA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ba065ebc-9056-4931-b8e7-5e92f7101ed1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 8,639; copy number 2: 21,787; copy number 3: 12,040; copy number 4: 9,105; copy number 5: 5,405; copy number 6: 2,303; copy number 7: 383; copy number 8: 49; copy number 9: 1; copy number 12: 26; copy number 17: 55.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AJ-A3IA-01A-11D-A20R-01): tumor purity 0.53, ploidy 2.73, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:81,666,477–82,866,508, 14 genes: AC013262.1, RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3.
- chr11:134,655,769–135,075,908, 10 genes: AP001999.3, AP001999.1, AP001999.2, LINC02706, LINC02714, AP003062.2, LINC02697, AP003062.1, LINC02717, LINC02684.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,158 genes in 39 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,412,027–4,484,375, 2 genes, copy number 7: LINC01777, AL355602.1.
- chr1:6,555,307–24,472,976, 539 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr1:152,719,522–175,880,468, 754 genes, copy number 5 (broad region; genes not listed).
- chr1:202,070,841–248,919,946, 1,074 genes, copy number 5–6 (broad region; genes not listed).
- chr2:108,322,238–111,699,033, 85 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:111,675,026–111,675,343, 1 gene, copy number 5: RPL34P8.
- chr2:153,158,938–214,410,501, 910 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr4:85,475,150–87,462,280, 28 genes, copy number 5–6 (within-gene range 2–6): ARHGAP24, MIR4451, MAPK10, MAPK10-AS1, RN7SKP96, MIR4452, PTPN13, SLC10A6, AC093827.1, C4orf36, AC093827.2, AC093827.5, AC093827.3, AC093827.4, AFF1, TECRP1, KLHL8, AC092658.1, GAPDHP60, AC108516.1, MIR5705, HSD17B13, AC108516.2, HSD17B11, RN7SL681P, AC112250.1, NUDT9, AC112250.2.
- chr4:88,330,176–89,999,409, 32 genes, copy number 6: Y_RNA, AC107067.2, AC107067.1, HERC6, HERC5, NCOA4P2, PYURF, PIGY, AC098582.1, PIGY-DT, AC083829.1, RN7SKP244, HERC3, RNU6-33P, NAP1L5, FAM13A-AS1, AC108065.2, AC108065.1, FAM13A, TIGD2, AC104785.1, RNU6-907P, GPRIN3, AC093866.1, AC097478.4, SNCA, AC097478.1, AC097478.3, AC097478.2, SNCA-AS1, MMRN1, AC105445.1.
- chr5:58,198–26,013,025, 416 genes, copy number 5–6 (broad region; genes not listed).
- chr5:26,669,346–37,966,964, 170 genes, copy number 5–7 (broad region; genes not listed).
- chr5:38,197,432–45,895,970, 121 genes, copy number 5–7 (broad region; genes not listed).
- chr6:167,607–20,042,940, 342 genes, copy number 5 (broad region; genes not listed).
- chr6:70,345,919–70,351,802, 1 gene, copy number 6: AL080275.1.
- chr6:85,155,667–85,290,849, 4 genes, copy number 5: AL139806.1, AL122016.1, AL135903.1, KRT18P64.
- chr6:130,013,699–131,063,322, 8 genes, copy number 5 (within-gene range 3–5): L3MBTL3, AL355581.1, SAMD3, TMEM200A, Y_RNA, AL583803.1, SMLR1, EPB41L2.
- chr6:135,851,701–136,195,574, 1 gene, copy number 5 (within-gene range 3–5): PDE7B.
- chr6:135,991,936–142,446,266, 93 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:88,808,318–108,443,496, 342 genes, copy number 5–12 (within-gene range 4–12) (broad region; genes not listed).
- chr8:126,474,189–143,840,973, 270 genes, copy number 5–7 (broad region; genes not listed).
- chr10:44,712–25,732,935, 427 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:1,970,786–2,697,950, 1 gene, copy number 6 (within-gene range 3–6): CACNA1C.
- chr12:2,217,462–3,286,564, 35 genes, copy number 6: AC005344.1, CACNA1C-AS4, CACNA1C-IT3, AC005293.1, AC005414.1, CACNA1C-AS3, AC007618.1, CACNA1C-AS2, CACNA1C-AS1, ITFG2-AS1, AC092471.2, LINC02371, IQSEC3P1, AC092471.1, RPL23AP14, CBX3P4, FKBP4, ITFG2-AS1, AC005841.1, ITFG2, NRIP2, TEX52, FOXM1, RHNO1, TULP3, AC005911.1, RNU6-1315P, TEAD4, AC125807.2, AC125807.1, TSPAN9, Metazoa_SRP, TSPAN9-IT1, AC005912.2, AC005912.1.
- chr12:3,300,698–3,325,343, 2 genes, copy number 6: AC005865.2, LINC02827.
- chr12:20,368,537–20,688,583, 1 gene, copy number 5 (within-gene range 4–5): PDE3A.
- chr12:20,551,590–32,993,754, 244 genes, copy number 5 (broad region; genes not listed).
- chr13:84,520,103–85,148,121, 7 genes, copy number 6: MTND4P1, MTND5P3, LINC00333, AL445588.1, AL356313.1, LINC00375, AL160154.1.
- chr14:76,761,468–81,436,465, 84 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr14:93,237,550–93,333,092, 1 gene, copy number 5 (within-gene range 4–5): BTBD7.
- chr14:93,333,219–101,563,452, 292 genes, copy number 5 (broad region; genes not listed).
- chr15:89,784,895–89,951,345, 11 genes, copy number 6 (within-gene range 4–6): ANPEP, AP3S2, ARPIN-AP3S2, MIR5094, AC027176.2, MIR5009, RNU6-1111P, ARPIN, RNU7-111P, AC027176.1, AC027176.3.
- chr15:92,393,881–92,620,015, 9 genes, copy number 6 (within-gene range 4–6): ST8SIA2, AC090985.1, ENO1P2, AC090985.2, C15orf32, LINC00930, AC091544.2, AC091544.4, AC091544.5.
- chr15:96,354,237–101,933,350, 134 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr18:47,390–8,406,861, 155 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:21,997,648–23,031,818, 55 genes, copy number 17: BNIP3P28, AC003973.1, ZNF257, BNIP3P29, ZNF92P2, AC073539.2, PCGF7P, MTDHP5, VN1R85P, ZNF676, BNIP3P30, AC073539.14, AC073539.1, AC073539.3, ZNF729, BNIP3P31, AC011494.1, RPL34P34, ZNF98, AC011516.1, BNIP3P32, AC025811.1, BNIP3P33, ZNF209P, AC004004.1, AC011467.6, AC011467.1, LINC01233, RNU6-1179P, AC011467.5, GOLGA2P9, RN7SL860P, AC011467.3, AC011467.4, RAD54L2P1, LINC01785, AC011467.2, ZNF492, AC024563.1, ZNF849P, RPL34P33, AC024563.2, VN1R87P, ZNF99, AC008626.2, AC008626.1, BNIP3P34, ZNF723, BNIP3P35, VN1R88P, AC022145.1, AC022145.2, ZNF728, BNIP3P36, LINC01859.
- chr19:42,397,128–42,652,355, 1 gene, copy number 7 (within-gene range 4–7): LIPE-AS1.
- chr19:42,472,875–58,213,562, 1,038 genes, copy number 5–7 (broad region; genes not listed).
- chr20:44,355,700–54,859,812, 266 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:58,309,715–64,313,132, 202 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,267. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
